Somatic mutation profile of tumor specimen 0DUKIC from CCDI case PBCLGT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.7 years (619 days).
Specimen 0DUKIC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0891c0a1-1944-4bfd-8fb6-a521da02b3a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUKIR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a63089d7-3f17-43de-bf0f-21bdfef76d9b

The open-access MAF lists 24 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 9, Missense Mutation 6, 3'UTR 3, Silent 3, Splice Site 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ1B | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 20/182 reads (11%) | catalogued as COSV59989381; called by muse, varscan2
- PDGFRA | c.1154A>T p.K385M | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57264818; called by muse, varscan2
- AMY2B | c.879-1G>A p.X293_splice | Splice Site (SNP) | VAF 10/88 reads (11%) | called by muse, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, varscan2
- EPRS1 | c.2542G>C p.A848P | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.633); called by muse, varscan2
- VPS13A | c.3211A>T p.N1071Y | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, varscan2
- ZNF578 | c.1620A>T p.K540N | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, varscan2
- CD180 | c.681G>A p.L227= | Silent (SNP) | VAF 39/158 reads (25%) | catalogued as rs1192077978, COSV56518622; called by muse, varscan2
- PDGFRA | c.1155G>A p.K385= | Silent (SNP) | VAF 88/232 reads (38%) | called by muse, varscan2
- RPL4 | c.444T>G p.P148= | Silent (SNP) | VAF 18/165 reads (11%) | called by muse, varscan2
- ADAM17 | c.619+76G>T | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, varscan2
- BRAF | c.2113-90G>T | Intron (SNP) | VAF 6/26 reads (23%) | called by muse, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 18/157 reads (11%) | called by muse, varscan2
- CTSC | c.318+6725T>G | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, varscan2
- GLCCI1 | c.696+91A>G | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, varscan2
- GTF2A1 | c.*23A>T | 3'UTR (SNP) | VAF 16/130 reads (12%) | called by muse, varscan2
- KMT2E | c.2196+14G>T | Intron (SNP) | VAF 13/128 reads (10%) | called by muse, varscan2
- LARP4 | c.1334+88A>C | Intron (SNP) | VAF 8/66 reads (12%) | called by muse, varscan2
- NRCAM | c.-57C>A | 5'UTR (SNP) | VAF 19/156 reads (12%) | catalogued as rs926414386, COSV100695372; called by muse, varscan2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 12/32 reads (38%) | catalogued as rs1012935800, COSV58726711; called by muse, varscan2
- SENP6 | c.2288+11A>T | Intron (SNP) | VAF 16/154 reads (10%) | called by muse, varscan2
- SIMC1 | c.1677+98T>C | Intron (SNP) | VAF 10/63 reads (16%) | catalogued as COSV104418257; called by muse, varscan2
- ZNF277 | c.801+32A>T | Intron (SNP) | VAF 12/130 reads (9%) | called by muse, varscan2
